Somatic mutation profile of tumor specimen C3N-01024-03 (aliquot CPT0105230009) from CPTAC case C3N-01024, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 66.0 years (24,110 days).
Specimen C3N-01024-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddaec2d9-a891-4436-81b7-0f6cedcf96c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01024-31 (Blood Derived Normal), aliquot CPT0107680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc896841-e92d-4f43-8625-f25529529b1c

The open-access MAF lists 87 somatic variants for this specimen: 58 protein-altering or splice-affecting, 20 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 20, Nonsense Mutation 7, In Frame Del 3, Intron 3, 3'Flank 2, 3'UTR 2, Splice Region 1, Frame Shift Del 1, 5'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 39/197 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 92/414 reads (22%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.653T>G p.V218G | Missense Mutation (SNP) | VAF 179/409 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555525743, COSV52690974, COSV52712839, COSV52761003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQR | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs201758262, COSV50056278; called by muse, mutect2, varscan2
- ARHGAP33 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as rs747730101; called by muse, mutect2, varscan2
- ATP2B3 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54847560; called by muse, mutect2
- CACNA1E | c.4102G>A p.V1368I | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs574530214, COSV62402477; called by muse, mutect2, varscan2
- CARMIL2 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV58031123; called by muse, mutect2, varscan2
- CCDC114 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs560134827, COSV59556552; called by muse, mutect2, varscan2
- CCDC85A | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.161); catalogued as rs746024337, COSV68147315; called by muse, mutect2, varscan2
- CROCC | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 31/285 reads (11%) | catalogued as rs775975023; called by muse, mutect2, varscan2
- CTNNA2 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63561718; called by muse, mutect2, varscan2
- DBX2 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs781083157, COSV100224417, COSV60337074; called by muse, mutect2, varscan2
- EGFLAM | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 102/365 reads (28%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs750333897, COSV59304288, COSV59310635; called by muse, mutect2, varscan2
- FBN2 | c.4423G>A p.E1475K | Missense Mutation (SNP) | VAF 169/640 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756919574, COSV99325694; called by muse, mutect2, varscan2
- HTR3E | c.1115C>T p.P372L (on ENST00000415389 / NM_001256613.1; = p.P387L on NM_182589.2) | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs763844964, COSV58945882; called by muse, mutect2, varscan2
- INSL5 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 99/303 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs372109860; called by muse, mutect2, varscan2
- KCNA4 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 102/325 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV60250440; called by muse, mutect2, varscan2
- KMT2D | c.12263C>G p.S4088C | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV56485471; called by muse, mutect2, varscan2
- MUC12 | c.3011C>T p.T1004M (on ENST00000379442; = p.T861M on NM_001164462.1) | Missense Mutation (SNP) | VAF 128/600 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.788); catalogued as rs752516653; called by muse, varscan2
- MUC17 | c.3668G>A p.S1223N | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs756946354; called by muse, mutect2, varscan2
- MYRIP | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs755354103; called by muse, mutect2, varscan2
- NELFA | c.1081C>T p.R361W (on ENST00000542778; = p.R350W on NM_005663.5) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as rs776937399; called by muse, mutect2, varscan2
- NLGN1 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64341130; called by muse, mutect2
- OR51B5 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as COSV56176705; called by muse, mutect2, varscan2
- PCDHGB4 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 91/311 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as rs748559328, COSV53895525; called by muse, mutect2, varscan2
- SI | c.1281C>T p.D427= | Splice Region (SNP) | VAF 55/472 reads (12%) | catalogued as rs1328457166; called by muse, mutect2, varscan2
- TEX46 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.027); catalogued as rs1487781219; called by muse, varscan2
- ZFP57 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1300159881; called by muse, mutect2, varscan2
- ZNF385D | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1419009725; called by muse, mutect2, varscan2
- ZNF804A | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as COSV56473452; called by muse, mutect2, varscan2
- ACACB | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADAM32 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2
- ADGRG4 | c.9206-2A>G p.X3069_splice | Splice Site (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
- CAMK4 | c.756_758del p.R253del | In Frame Del (DEL) | VAF 26/151 reads (17%) | called by mutect2, pindel, varscan2
- DBX1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- EFEMP1 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 57/373 reads (15%) | called by muse, mutect2, varscan2
- EIF3A | c.1682C>A p.S561* | Nonsense Mutation (SNP) | VAF 32/223 reads (14%) | called by muse, mutect2, varscan2
- ESPN | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- FGF17 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2
- MAPK10 | c.718C>T p.Q240* (on ENST00000359221 / NM_001351625.2; = p.Q278* on NM_002753.5) | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | called by muse, mutect2, varscan2
- MED12 | c.6169C>T p.Q2057* | Nonsense Mutation (SNP) | VAF 106/296 reads (36%) | called by muse, varscan2
- MMS19 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); called by muse, varscan2
- MSL1 | c.686_688del p.Q229del | In Frame Del (DEL) | VAF 131/516 reads (25%) | called by mutect2, pindel, varscan2
- NKX6-1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2
- OTUD7A | c.1790C>A p.S597* (on ENST00000307050 / NM_001382637.1; = p.S590* on NM_130901.3) | Nonsense Mutation (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- PATE4 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PAX9 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 587/901 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PEBP1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 193/598 reads (32%) | called by muse, mutect2, varscan2
- PIEZO2 | c.6642C>G p.H2214Q | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TBX4 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 89/310 reads (29%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TCP1 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TP53I11 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 99/329 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- TRIML1 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 87/377 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ZNF181 | c.1167C>A p.S389R | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZNF625 | c.566G>C p.G189A | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); called by muse, mutect2
- ZNF639 | c.356_360del p.S119* | Frame Shift Del (DEL) | VAF 48/156 reads (31%) | called by mutect2, pindel
- ZNF730 | c.662G>T p.R221I | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATG2A | c.3102G>A p.S1034= | Silent (SNP) | VAF 112/378 reads (30%) | catalogued as rs765928567, COSV101034337; called by muse, mutect2, varscan2
- CSMD3 | c.7224G>A p.T2408= (on ENST00000297405 / NM_001363185.1; = p.T2304= on NM_052900.3) | Silent (SNP) | VAF 192/436 reads (44%) | catalogued as rs781779613, COSV52212247, COSV52298395; called by muse, mutect2, varscan2
- DTX3L | c.522G>T p.V174= | Silent (SNP) | VAF 53/290 reads (18%) | called by muse, mutect2, varscan2
- FRAS1 | c.1020T>G p.P340= | Silent (SNP) | VAF 59/243 reads (24%) | called by muse, mutect2, varscan2
- GNAS | c.1629G>A p.P543= | Silent (SNP) | VAF 28/688 reads (4%) | called by muse, mutect2
- HTR1E | c.417C>T p.A139= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs146428063, COSV100541098; called by muse, mutect2, varscan2
- KAT7 | c.1267C>T p.L423= | Silent (SNP) | VAF 89/301 reads (30%) | called by muse, mutect2, varscan2
- KHDRBS1 | c.144A>G p.G48= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- MAST1 | c.255C>T p.D85= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs201497430, COSV52256211; called by mutect2, varscan2
- MCM4 | c.940C>A p.R314= | Silent (SNP) | VAF 29/241 reads (12%) | called by muse, mutect2, varscan2
- MYO9A | c.3294G>A p.R1098= | Silent (SNP) | VAF 124/397 reads (31%) | called by muse, varscan2
- NDRG1 | c.720G>A p.E240= | Silent (SNP) | VAF 141/577 reads (24%) | catalogued as rs1400704810; called by muse, mutect2, varscan2
- NLRP4 | c.1278C>T p.D426= | Silent (SNP) | VAF 148/333 reads (44%) | catalogued as rs879064268; called by muse, mutect2, varscan2
- PCDHA1 | c.699C>T p.L233= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as rs1230076426, COSV65373715; called by muse, mutect2, varscan2
- PCDHB7 | c.1866C>T p.G622= | Silent (SNP) | VAF 167/1591 reads (10%) | catalogued as COSV50766245; called by muse, mutect2, varscan2
- PRAMEF19 | c.117G>T p.L39= | Silent (SNP) | VAF 51/456 reads (11%) | called by muse, mutect2, varscan2
- SAMD13 | c.315C>T p.Y105= (on ENST00000370671; = p.Y99= on NM_001010971.3) | Silent (SNP) | VAF 43/164 reads (26%) | catalogued as rs374324643, COSV65744540; called by muse, mutect2, varscan2
- SH2D4B | c.1038G>A p.E346= | Silent (SNP) | VAF 27/94 reads (29%) | called by muse, varscan2
- SLC26A3 | c.1755C>T p.G585= | Silent (SNP) | VAF 149/574 reads (26%) | called by muse, mutect2, varscan2
- SYCP2 | c.2223G>A p.K741= | Silent (SNP) | VAF 46/225 reads (20%) | catalogued as COSV62770226; called by muse, mutect2, varscan2
- AC022364.1 | chr12:28183739 G>A | 3'Flank (SNP) | VAF 91/218 reads (42%) | called by muse, mutect2, varscan2
- ALG2 | c.*1147C>T | 3'UTR (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- CTSH | c.406-1088T>G | Intron (SNP) | VAF 19/97 reads (20%) | catalogued as rs1377049571; called by muse, mutect2, varscan2
- DPY30 | chr2:32023738 A>C | 3'Flank (SNP) | VAF 42/269 reads (16%) | called by muse, mutect2, varscan2
- FAM169B | n.766G>T | RNA (SNP) | VAF 69/244 reads (28%) | called by muse, mutect2, varscan2
- GABRA1 | c.1060-17G>A | Intron (SNP) | VAF 29/227 reads (13%) | called by muse, mutect2, varscan2
- ISM2 | c.141+141G>A | Intron (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- TMEM141 | chr9:136791328 del CCGCCTGCGCCTGCGCAGGC | 5'UTR (DEL) | VAF 38/332 reads (11%) | called by mutect2, pindel
- XPA | c.*75_*77delinsAAA | 3'UTR (TNP) | VAF 6/46 reads (13%) | called by muse*, pindel
